Surgical pathology report (de-identified scan), TCGA case TCGA-BQ-5883, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma), tissue source site MSKCC, specimen TCGA-BQ-5883-01A (Primary Tumor).

[page 1 of 2]
Clinical Diagnosis & History:

Right kidney tumor.

Specimens Submitted:

- 1: SP: Kidney, right superior pole margin, biopsy
2: SP: Kidney, right, partial nephrectomy

DIAGNOSIS:

1. Soft tissue, "superior pole margin right kidney," biopsy:
Benign adipose tissue.

2. SP: Kidney, right, partial nephrectomy:
Tumor Type:
Renal cell carcinoma - Unclassified type
See note

Tumor Size:
Greatest diameter is 2.5 cm.

Local Invasion (for renal cortical types):
Not Identified

Renal Vein Invasion:
Not identified

Surgical Margins:
Free of tumor

Non-Neoplastic Kidney:
Unremarkable

Adrenal Gland:
Not identified

Lymph Nodes:
Not identified

Staging for renal cell carcinoma/oncocytoma:
pT1 Tumor <= 7.0 cm in greatest dimension limited to the kidney

Note: The tumor shows mixed features with both tubulopapillary and cystic architecture and is comprised of cells with abundant eosinophilic cytoplasm, frequent cytoplasmic vacuoles, and round, overall uniform nuclei. These findings are compatible with a low grade renal cell carcinoma. This case was seen in consultation with [REDACTED] who concurs with the diagnosis.

[page 2 of 2]
I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

Gross Description:

1). The specimen is received fresh for frozen section consultation, labeled "superior pole margin, right kidney tumor" and consists of three fragments of tan tissue measuring 0.7 x 0.6 x 0.5 cm. Entirely submitted for frozen section.

Summary of sections:
FSC -- frozen section control

2). The specimen is received fresh for frozen section and is labeled "right kidney tumor suture on the base." It consists of a 2.9 x 2.5 x 2.5 cm wedge shaped portion of kidney with a suture marking the deep margin. The margin is inked black and the specimen is serially sectioned to reveal a yellow-brown mass measuring 2.5 x 2.5 x 2.5 cm. The clearance from the resection margin is 0.2 cm. A representative section of the nearest margin is submitted for frozen section diagnosis. Representatively submitted.

Summary of sections:
FSC - frozen section control
T - tumor
M - margin
RS - representative sections

Summary of Sections:

Part 1: SP: Kidney, right superior pole margin, biopsy

Block	Sect. Site	PCs
1	fsc	1

Part 2: SP: Kidney, right, partial nephrectomy

Block	Sect. Site	PCs
1	fsc	1
1	m	1
1	rs	1
2	t	2

Intraoperative Consultation:

Note: The diagnoses given in this section pertain only to the tissue sample examined at the time of the intraoperative consultation.

- 1) FROZEN SECTION DIAGNOSIS: BENIGN FIBROFATTY TISSUE.
PERMANENT DIAGNOSIS: SAME
- 2) FROZEN SECTION DIAGNOSIS: RENAL CORTICAL TUMOR. MARGIN IS FREE (APPROXIMATELY 2 MM CLEARANCE).
PERMANENT DIAGNOSIS: SAME

Source: NCI Genomic Data Commons file ffe25ca3-1b88-4326-9eb7-adde0340c40b (TCGA-BQ-5883.AED6B38D-A2F5-45C2-92D7-93831C9B1420.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).